Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A5F2, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A5F2-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount per container	Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					female	Caucasian (White)	Glioma		Brain, right frontal lobe	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Astrocytoma	2	n/a	n/a	n/a	none	n/a	90
					female	Caucasian (White)	Glioma		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-O-3
Astrocytoma NOS 9400/3
Site ⑧ Brain, Supratentorial C71.0
JW 4/2/13

TCGA-P5-AS5F2-01A-PR Redacted

H&P&A Discrepancy		✓
Primary/Synchronous Primary Disease		✓

Source: NCI Genomic Data Commons file deef71c8-d563-47c0-a5b6-9d4c8ed1618f (TCGA-P5-A5F2.0DC839C0-415F-48FB-92A8-44B06A7A5309.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).